Somatic mutation profile of tumor specimen 0DSS5Q from CCDI case PBCIRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.4 years (527 days).
Specimen 0DSS5Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9307662-ce7e-48f7-a5ab-72552d40ae11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSS6C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe447351-048d-48b7-99ea-f80e20c5d7a7

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, In Frame Ins 1, Silent 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP5 | c.4273C>T p.R1425* (on ENST00000345122 / NM_001030055.2; = p.R1424* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 79/548 reads (14%) | catalogued as COSV53735141; called by muse, mutect2, varscan2
- FMNL2 | c.1665_1666insTCG p.P555_P556insS | In Frame Ins (INS) | VAF 16/209 reads (8%) | catalogued as rs745757749; called by mutect2, pindel
- INF2 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs757277927, COSV53036530; called by muse, mutect2, varscan2
- CLPSL1 | c.210G>C p.L70= | Silent (SNP) | VAF 96/359 reads (27%) | catalogued as rs778065535; called by muse, mutect2, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- NAA40 | c.411-14C>G | Intron (SNP) | VAF 31/322 reads (10%) | called by muse, mutect2, varscan2
- SF1 | c.237-36G>A | Intron (SNP) | VAF 32/192 reads (17%) | catalogued as rs1387358225, COSV99918126; called by muse, mutect2, varscan2
